MMRF case MMRF_1928 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/9f18c922-5fcf-45f9-82fc-111d2aa6d6d7

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 53 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 53.2 years (19,425 days); ISS stage: I; Days to last known disease status: 952 days (2.6 years); Days to last follow up: 952 days (2.6 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 119 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 123 days; Days to treatment end: 123 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 138 days; Days to treatment end: 169 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 148 days; Days to treatment end: 169 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 170 days; Days to treatment end: 170 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 171 days; Days to treatment end: 171 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 276 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -42 (ECOG 0): M Protein 5.58 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 127 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.09 mg/dL; Immunoglobulin G 62.6 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 2.9 µg/mL; Lactate Dehydrogenase 2.33 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 93 µmol/L; Calcium 2.31 mmol/L; Albumin 37 g/L; Total Protein 11.8 g/dL; Glucose 5.3 mmol/L.
- Day 35 (ECOG 0): M Protein 3.37 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 44.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.08 mg/dL; Immunoglobulin G 39.1 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 6.01 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 125 ×10⁹/L; Creatinine 110 µmol/L; Calcium 2.18 mmol/L; Albumin 36 g/L; Total Protein 9.4 g/dL; Glucose 6 mmol/L.
- Day 138 (ECOG 0): M Protein 1.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 12.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.61 mg/dL; Immunoglobulin G 18.3 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 3.67 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.73 ×10⁹/L; Platelets 136 ×10⁹/L; Creatinine 86 µmol/L; Calcium 2.24 mmol/L; Albumin 40 g/L; Total Protein 7.4 g/dL; Glucose 4.9 mmol/L.
- Day 238 (ECOG 1): M Protein 7.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.07 mg/dL; Immunoglobulin G 12.5 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 198 ×10⁹/L; Creatinine 92 µmol/L; Calcium 2.31 mmol/L; Total Protein 7.6 g/dL; Glucose 8.7 mmol/L.
- Day 329 (ECOG 1): M Protein 9.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.88 mg/dL; Immunoglobulin G 16.1 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.21 g/L; Hemoglobin 7.44 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 142 ×10⁹/L; Creatinine 82 µmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 7.3 g/dL; Glucose 4.4 mmol/L.
- Day 411 (ECOG 2): M Protein 8.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.31 mg/dL; Immunoglobulin G 14.7 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 7.44 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 121 ×10⁹/L; Creatinine 94 µmol/L; Calcium 2.27 mmol/L; Albumin 40 g/L; Total Protein 7.4 g/dL; Glucose 5.2 mmol/L.
- Day 495 (ECOG 1): M Protein 9.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.51 mg/dL; Immunoglobulin G 15.5 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 111 ×10⁹/L; Creatinine 89 µmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 7.2 g/dL; Glucose 5.2 mmol/L.
- Day 602 (ECOG 1): M Protein 9.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.08 mg/dL; Immunoglobulin G 16 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 7.25 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 106 ×10⁹/L; Creatinine 98 µmol/L; Calcium 2.19 mmol/L; Albumin 41 g/L; Total Protein 7 g/dL; Glucose 5.2 mmol/L.
- Day 684 (ECOG 2): M Protein 1.18 g/dL; Immunoglobulin G 22.7 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 2.27 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 93 ×10⁹/L; Creatinine 97 µmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 7.4 g/dL; Glucose 5.6 mmol/L.
- Day 763 (ECOG 1): M Protein 1.27 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.74 mg/dL; Immunoglobulin G 17.9 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 7.25 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 94 ×10⁹/L; Creatinine 108 µmol/L; Calcium 2.26 mmol/L; Albumin 43 g/L; Total Protein 7.6 g/dL; Glucose 5.9 mmol/L.
- Day 847 (ECOG 1): M Protein 1.39 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 22.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.71 mg/dL; Immunoglobulin G 20.3 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 7.44 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 92 ×10⁹/L; Creatinine 95 µmol/L; Calcium 2.34 mmol/L; Albumin 42 g/L; Total Protein 7.7 g/dL; Glucose 3.8 mmol/L.
- Day 952 (ECOG 1): M Protein 1.59 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 29.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.79 mg/dL; Immunoglobulin G 25.9 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 6.94 mmol/L; Leukocytes 2.3 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 101 ×10⁹/L; Creatinine 100 µmol/L; Calcium 2.32 mmol/L; Albumin 38 g/L; Total Protein 8 g/dL; Glucose 6 mmol/L.

Other clinical attributes
- Day -42: Weight: 86 kg; Height: 179 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Melanoma; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1928_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -42 days.
- Sample MMRF_1928_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -42 days.
